Gene-level copy-number profile of tumor specimen TCGA-GJ-A6C0-01A from TCGA case TCGA-GJ-A6C0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 75.6 years (27,626 days).
Specimen TCGA-GJ-A6C0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ab977988-8c28-4f41-a661-5c9355ec540c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GJ-A6C0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9f0d91c-86ec-4845-9c8b-2e1cbd17cb05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 6,253; copy number 2: 48,144; copy number 3: 5,279; copy number 4: 112; copy number 5: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GJ-A6C0-01A-12D-A30U-01): tumor purity 0.77, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:93,306,429–93,806,272, 10 genes (within-gene range 0–1): MYOF, CEP55, RNA5SP323, FFAR4, RBP4, PDE6C, FRA10AC1, LGI1, AL157396.1, AL358154.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,028,179–20,275,005, 8 genes, copy number 5 (within-gene range 3–5): PLA2G5, PLA2G2D, PLA2G2F, Z98257.1, PLA2G2C, UBXN10, LINC01757, Z98257.2.
- chr1:211,476,522–211,583,725, 4 genes, copy number 5: RD3, AC105275.1, SLC30A1, AC105275.2.
- chr10:5,498,697–5,499,570, 1 gene, copy number 5: CALML5.
- chr12:75,649,195–75,698,816, 4 genes, copy number 5: AC078820.2, RPL10P13, SNORA70, AC078820.1.

Autosomal genes at a single copy (total copy number 1): 6,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
